Somatic mutation profile of tumor specimen TCGA-85-8277-01A (aliquot TCGA-85-8277-01A-11D-2293-08) from TCGA case TCGA-85-8277, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.6 years (25,793 days).
Specimen TCGA-85-8277-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6963c3e3-ca05-492a-9a52-1f4025c8a9cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8277-10A (Blood Derived Normal), aliquot TCGA-85-8277-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/196db57c-7a32-49e4-a33d-8dc7bcf2512a

The open-access MAF lists 264 somatic variants for this specimen: 196 protein-altering or splice-affecting, 63 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 63, Nonsense Mutation 14, Frame Shift Del 9, Splice Site 7, Intron 3, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 82/115 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSS3 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54102423; called by muse, mutect2, varscan2
- ADAM7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV51535702; called by muse, mutect2, varscan2
- ANKRD30A | c.928G>T p.V310L (on ENST00000611781; = p.V254L on NM_052997.2) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.097); catalogued as COSV100653970; called by muse, mutect2, varscan2
- ANTXR1 | c.952-2A>T p.X318_splice | Splice Site (SNP) | VAF 46/136 reads (34%) | catalogued as COSV100362938; called by muse, varscan2
- AP002512.3 | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); catalogued as rs1296152931; called by muse, mutect2, varscan2
- ARHGAP22 | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 154/290 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs370486035; called by muse, mutect2, varscan2
- ASCC3 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1226193895; called by muse, mutect2, varscan2
- ATN1 | c.3512C>T p.P1171L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.979); catalogued as rs782161422; called by muse, mutect2, varscan2
- BCLAF1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62144176; called by muse, mutect2, varscan2
- CACNG3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 143/300 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs753398983, COSV99136279; called by muse, mutect2, varscan2
- CARD18 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs756406825; called by muse, mutect2, varscan2
- CDC42BPG | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1281113744, COSV61349557; called by muse, mutect2, varscan2
- CDH10 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100050270; called by muse, mutect2, varscan2
- CEP192 | c.3593G>T p.R1198I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs749236118, COSV58063255; called by muse, mutect2, varscan2
- CNTN5 | c.2295G>A p.M765I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54341408; called by muse, mutect2, varscan2
- COBL | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs753085874, COSV54344159; called by muse, mutect2, varscan2
- CPED1 | c.2311-2A>T p.X771_splice | Splice Site (SNP) | VAF 74/146 reads (51%) | catalogued as COSV100121346; called by muse, mutect2, varscan2
- CREBBP | c.1937G>T p.S646I | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52118323; called by muse, mutect2, varscan2
- DACH2 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs888172719; called by muse, mutect2, varscan2
- DDX59 | c.1725A>T p.L575F | Missense Mutation (SNP) | VAF 274/374 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1405454627; called by muse, mutect2, varscan2
- DECR1 | c.886-1G>T p.X296_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99616494; called by muse, mutect2, varscan2
- DEFB110 | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV101182429; called by muse, mutect2, varscan2
- DEPTOR | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs200382706; called by muse, mutect2, varscan2
- DISP2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs148317482; called by muse, mutect2, varscan2
- DSCAM | c.5842A>G p.M1948V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs764531499; called by muse, mutect2, varscan2
- DSCAML1 | c.1484C>T p.P495L (on ENST00000321322; = p.P435L on NM_020693.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392885362, COSV58402183; called by muse, mutect2, varscan2
- DUSP21 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 35/54 reads (65%) | catalogued as rs1262716156; called by muse, mutect2, varscan2
- EFCAB5 | c.2207del p.K736Rfs*16 | Frame Shift Del (DEL) | VAF 69/99 reads (70%) | catalogued as rs755823613; called by mutect2, varscan2
- ETV3L | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV71901131; called by muse, mutect2, varscan2
- FA2H | c.363+2T>C p.X121_splice | Splice Site (SNP) | VAF 150/376 reads (40%) | catalogued as COSV99547898; called by muse, mutect2, varscan2
- FAM131B | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 56/127 reads (44%) | catalogued as COSV58374340; called by muse, mutect2, varscan2
- FAM47C | c.1049G>C p.G350A | Missense Mutation (SNP) | VAF 102/145 reads (70%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.5); catalogued as COSV63726254; called by muse, mutect2, varscan2
- FRMPD3 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1242021398, COSV52191711; called by muse, mutect2, varscan2
- GABBR1 | c.2308C>T p.L770F | Missense Mutation (SNP) | VAF 54/441 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63541033; called by muse, mutect2, varscan2
- GFAP | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1236176019, COSV99493558; called by muse, mutect2, varscan2
- GLT1D1 | c.850G>T p.V284F (on ENST00000442111 / NM_001366889.1; = p.V204F on NM_144669.3) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV99896635, COSV99897815; called by muse, mutect2, varscan2
- GPRIN2 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV100966436; called by muse, mutect2
- GPSM1 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs782499031; called by muse, mutect2, varscan2
- HLTF | c.761G>C p.R254P | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59502046, COSV59503818; called by muse, mutect2, varscan2
- INPP5A | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1048221979, COSV61248224; called by muse, mutect2, varscan2
- ITIH1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775722288, COSV99834792; called by muse, mutect2, varscan2
- KLF4 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101012796; called by muse, mutect2
- MAP3K9 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs1436945562; called by muse, mutect2, varscan2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 39/74 reads (53%) | catalogued as rs776720499; called by mutect2, pindel, varscan2
- MON1B | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs144793245; called by muse, mutect2, varscan2
- NBEAL2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs753275005, COSV52761018; called by muse, mutect2, varscan2
- NLRP11 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 68/114 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV64088711; called by muse, mutect2, varscan2
- NOTCH1 | c.4339G>C p.E1447Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.744); catalogued as COSV53061678; called by muse, mutect2, varscan2
- OCA2 | c.891-2A>T p.X297_splice | Splice Site (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100668485; called by muse, mutect2
- OR5H14 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 206/628 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101454251, COSV71193884; called by muse, mutect2
- OR5M10 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs938543296, COSV101595916; called by muse, mutect2, varscan2
- OTOL1 | c.441C>A p.Y147* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV60006107; called by muse, mutect2
- OTUB2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746431047, COSV52573752; called by muse, mutect2, varscan2
- RPP30 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as rs181966124; called by muse, mutect2, varscan2
- SBDS | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 82/292 reads (28%) | catalogued as COSV99886156; called by muse, mutect2, varscan2
- SCAP | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771404299, COSV55565192, COSV55565391; called by muse, mutect2, varscan2
- SEC16A | c.5566C>T p.R1856* | Nonsense Mutation (SNP) | VAF 51/106 reads (48%) | catalogued as COSV51523673; called by muse, mutect2, varscan2
- SHROOM3 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1390418875; called by muse, mutect2, varscan2
- SIPA1L2 | c.3236G>C p.R1079T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs768415530; called by muse, mutect2, varscan2
- SLC1A2 | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV99554758; called by muse, mutect2, varscan2
- SOX3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100983757; called by muse, mutect2, varscan2
- SPAG16 | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59070887, COSV59133810; called by muse, mutect2, varscan2
- SPTAN1 | c.6848C>T p.T2283M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100823441; called by muse, mutect2, varscan2
- SPTBN2 | c.1504A>T p.I502F | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs751351000; called by muse, mutect2, varscan2
- SSX5 | c.331-2A>C p.X111_splice (on ENST00000347757 / NM_175723.1; = p.X152_splice on NM_021015.4) | Splice Site (SNP) | VAF 198/283 reads (70%) | catalogued as COSV100308863; called by muse, mutect2, varscan2
- STAB2 | c.2441G>A p.C814Y | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1312894586; called by muse, mutect2, varscan2
- SYNE1 | c.4186G>A p.A1396T (on ENST00000367255 / NM_182961.4; = p.A1403T on NM_033071.3) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV54965715; called by muse, mutect2, varscan2
- SZT2 | c.4565G>A p.G1522E (on ENST00000634258 / NM_001365999.1; = p.G1465E on NM_015284.4) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65167149; called by muse, mutect2, varscan2
- TC2N | c.638-1G>C p.X213_splice | Splice Site (SNP) | VAF 36/117 reads (31%) | catalogued as COSV61747745; called by muse, mutect2, varscan2
- TCF20 | c.5783G>C p.R1928T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59493167; called by muse, mutect2, varscan2
- TLR4 | c.243G>T p.Q81H (on ENST00000355622 / NM_138554.5; = p.Q41H on NM_003266.4) | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV100790625; called by muse, mutect2, varscan2
- TMTC3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV57122554; called by muse, mutect2, varscan2
- TNRC18 | c.8551A>T p.N2851Y | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100079082; called by muse, mutect2, varscan2
- TTN | c.89553C>A p.S29851R (on ENST00000591111; = p.S22427R on NM_003319.4) | Missense Mutation (SNP) | VAF 122/303 reads (40%) | PolyPhen probably damaging (0.997); catalogued as COSV100619594; called by muse, mutect2, varscan2
- TUBGCP3 | c.2408G>T p.R803L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV56184561; called by muse, mutect2
- UBXN8 | c.447C>G p.N149K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV99668048; called by muse, mutect2, varscan2
- USH2A | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs776211037, COSV56358147; called by muse, mutect2, varscan2
- VPREB1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs375221058; called by muse, mutect2, varscan2
- WDR70 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54272097; called by muse, mutect2, varscan2
- ZEB2 | c.2486del p.S829Ifs*3 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | catalogued as COSV100355754; called by mutect2, pindel, varscan2
- ZNF266 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1177111337; called by muse, mutect2, varscan2
- ZNF585B | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as rs560027860; called by muse, mutect2, varscan2
- ZNF708 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63608365; called by muse, mutect2, varscan2
- ZNF878 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV72155984; called by muse, mutect2, varscan2
- ZP3 | c.1082C>A p.T361N (on ENST00000394857 / NM_001110354.2; = p.T310N on NM_007155.6) | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100334669; called by mutect2, varscan2
- ZRANB3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51496649; called by muse, mutect2, varscan2
- ACCSL | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ADAMTSL3 | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADGRE2 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AIMP1 | c.397A>C p.K133Q | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ALOX12 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AMIGO1 | c.1351C>A p.Q451K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD30A | c.1576G>A p.A526T (on ENST00000611781; = p.A470T on NM_052997.2) | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ATG2B | c.5809G>A p.A1937T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP10A | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- BAIAP2 | c.520_530del p.E174Lfs*138 | Frame Shift Del (DEL) | VAF 59/113 reads (52%) | called by mutect2, pindel, varscan2
- C10orf71 | c.1388A>T p.Q463L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- C2CD2L | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- C6orf118 | c.951A>C p.Q317H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAND1 | c.1514_1518del p.L505Qfs*32 | Frame Shift Del (DEL) | VAF 124/191 reads (65%) | called by mutect2, pindel, varscan2
- CD151 | c.330_340del p.A111Lfs*26 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.3454G>A p.G1152R | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CDKN2A | c.176_183del p.V59Afs*58 | Frame Shift Del (DEL) | VAF 17/28 reads (61%) | called by mutect2, varscan2
- CDX4 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRNA4 | c.168del p.N57Tfs*26 | Frame Shift Del (DEL) | VAF 41/138 reads (30%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUL5 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CWC22 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CYP1B1 | c.1052A>T p.D351V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DENND2C | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DMXL2 | c.8062G>C p.D2688H | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOC2A | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- DYSF | c.1179G>A p.Q393= | Splice Region (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- E2F7 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 102/192 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGF | c.3073G>C p.A1025P | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- EIF4G3 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1369G>T p.V457F (on ENST00000450689 / NM_001142749.3; = p.V290F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- FAM131A | c.775G>A p.E259K (on ENST00000310585; = p.E290K on NM_144635.5) | Missense Mutation (SNP) | VAF 22/657 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.591); called by muse, mutect2
- FHOD3 | c.3303T>A p.N1101K (on ENST00000359247 / NM_001281739.3; = p.N1118K on NM_025135.5) | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FOXD4L5 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by mutect2, varscan2
- FOXN1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FSTL5 | c.2006G>T p.S669I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABBR1 | c.2307G>T p.W769C | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GIGYF1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPC4 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 197/288 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR143 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT tolerated (0.14); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GRIK1 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 27/34 reads (79%) | called by muse, mutect2, varscan2
- HNRNPH3 | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HOXB3 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.715A>T p.N239Y (on ENST00000485419 / NM_001197113.1; = p.N163Y on NM_014575.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JHY | c.1856G>C p.S619T | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KEL | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL22 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- L3MBTL1 | c.2243T>C p.L748P (on ENST00000418998 / NM_001377303.1; = p.L658P on NM_015478.7) | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMB2 | c.4131G>C p.E1377D | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.5824A>C p.T1942P | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAST4 | c.5336C>A p.S1779Y (on ENST00000403625 / NM_001164664.2; = p.S1590Y on NM_015183.3) | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MCF2L2 | c.2617T>C p.Y873H | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MICAL3 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC6 | c.5093C>T p.T1698I | Missense Mutation (SNP) | VAF 97/910 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by mutect2, varscan2
- MXRA5 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- NAA30 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NOP9 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OIT3 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- OR10G2 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4P4 | c.107T>G p.I36S | Missense Mutation (SNP) | VAF 197/236 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR52B4 | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OR56B1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ORM1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA | c.1965G>T p.M655I | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PEAK1 | c.4639T>G p.Y1547D | Missense Mutation (SNP) | VAF 5/135 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- PIK3R2 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- PLXNB2 | c.3794A>G p.N1265S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PPIAL4A | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 58/387 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PTPRM | c.3015G>T p.R1005S | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBFOX1 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RFX6 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF138 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- RPAP1 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 89/130 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RYR2 | c.299T>A p.F100Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SHANK1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A48 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 82/159 reads (52%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC8A2 | c.1712T>G p.V571G | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, varscan2
- SMARCA1 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SORCS3 | c.2426A>G p.Y809C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SPATA31A1 | c.3076C>G p.Q1026E | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- SPATA31E1 | c.4206G>A p.W1402* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- SPEF2 | c.4115C>A p.T1372K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SPEF2 | c.4354C>A p.R1452S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPPL2B | c.807del p.C270Vfs*68 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- SPPL2C | c.1430C>A p.T477N | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SUPT5H | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 80/160 reads (50%) | called by muse, mutect2, varscan2
- SYNE1 | c.24509G>C p.G8170A (on ENST00000367255 / NM_182961.4; = p.G8099A on NM_033071.3) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.20031A>T p.L6677F | Missense Mutation (SNP) | VAF 156/271 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM16L | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRIM2 | c.1341G>C p.K447N (on ENST00000437508; = p.K474N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TTN | c.99252C>A p.D33084E (on ENST00000591111; = p.D25660E on NM_003319.4) | Missense Mutation (SNP) | VAF 86/181 reads (48%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.80500C>A p.P26834T (on ENST00000591111; = p.P19410T on NM_003319.4) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TTN | c.71514C>A p.F23838L (on ENST00000591111; = p.F16414L on NM_003319.4) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTN | c.32581G>T p.E10861* (on ENST00000591111; = p.E9934* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.32386A>G p.K10796E (on ENST00000591111; = p.K9869E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTN | c.10862C>A p.P3621H (on ENST00000591111; = p.P3575H on NM_003319.4) | Missense Mutation (SNP) | VAF 57/274 reads (21%) | called by muse, mutect2, varscan2
- TWSG1 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- UTRN | c.6844C>T p.Q2282* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- VNN1 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR37 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- XIRP2 | c.9737G>T p.G3246V (on ENST00000628543; = p.G3421V on NM_152381.6) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ZBBX | c.1718C>A p.S573* | Nonsense Mutation (SNP) | VAF 89/178 reads (50%) | called by muse, mutect2, varscan2
- ZBTB25 | c.755A>T p.N252I | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZDHHC8 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFYVE28 | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF345 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF433 | c.484A>T p.R162W | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ZNF714 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2
- ZNF827 | c.2800T>G p.C934G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCC12 | c.1140G>T p.V380= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- AC100868.1 | c.1185C>T p.I395= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- ACSM2A | c.1491A>G p.P497= (on ENST00000219054; = p.P418= on NM_001308169.2) | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as COSV54582141; called by muse, mutect2, varscan2
- ARFGEF3 | c.228G>C p.L76= | Silent (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- BBS4 | c.276A>G p.T92= | Silent (SNP) | VAF 83/131 reads (63%) | called by muse, mutect2, varscan2
- C22orf42 | c.432C>T p.H144= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs772350873, COSV66075189; called by muse, mutect2, varscan2
- C5orf24 | c.288C>T p.T96= | Silent (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- C9orf131 | c.1884G>A p.G628= | Silent (SNP) | VAF 144/252 reads (57%) | called by muse, mutect2, varscan2
- CA3 | c.549G>C p.L183= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs373717809; called by muse, mutect2, varscan2
- CACNA1C | c.2388G>T p.V796= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1346569150; called by muse, mutect2, varscan2
- CCNB3 | c.1740A>G p.V580= | Silent (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- CFAP69 | c.2475G>A p.T825= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as rs374396434; called by muse, mutect2
- CLCNKB | c.108G>A p.L36= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as rs1194236580; called by muse, mutect2, varscan2
- CNIH2 | c.240G>A p.L80= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100268528; called by muse, mutect2
- COL27A1 | c.2301G>T p.L767= | Silent (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- CPXM1 | c.285C>T p.P95= | Silent (SNP) | VAF 69/185 reads (37%) | called by muse, mutect2, varscan2
- CSPG5 | c.1269C>T p.C423= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1218913767, COSV53132487; called by muse, mutect2, varscan2
- CTNND2 | c.1935C>A p.L645= | Silent (SNP) | VAF 63/381 reads (17%) | called by muse, mutect2, varscan2
- DPEP1 | c.1164C>T p.S388= | Silent (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- EDNRB | c.1563C>T p.D521= (on ENST00000377211 / NM_001201397.1; = p.D431= on NM_000115.5) | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- EOGT | c.606C>T p.S202= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as COSV55153044; called by muse, mutect2, varscan2
- EPHA3 | c.1176C>A p.T392= | Silent (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- EPHB6 | c.1941C>T p.I647= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as rs377141828; called by muse, mutect2, varscan2
- FAM135B | c.2508T>A p.A836= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- FBN2 | c.1506T>A p.A502= | Silent (SNP) | VAF 73/119 reads (61%) | called by muse, mutect2, varscan2
- GPR55 | c.453C>T p.T151= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs375661190; called by muse, mutect2, varscan2
- GRIA4 | c.279C>A p.A93= | Silent (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- GRIN3A | c.1320C>G p.T440= | Silent (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- HECTD1 | c.852A>G p.S284= | Silent (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- IL1RAP | c.817C>T p.L273= | Silent (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- ING2 | c.345A>G p.A115= | Silent (SNP) | VAF 62/111 reads (56%) | called by muse, mutect2, varscan2
- KLC4 | c.1614T>A p.A538= | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- LAMA2 | c.1281C>A p.V427= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- MUC3A | c.8682A>G p.K2894= | Silent (SNP) | VAF 76/710 reads (11%) | catalogued as COSV100115221; called by muse, mutect2
- OR9Q1 | c.699G>A p.Q233= | Silent (SNP) | VAF 88/150 reads (59%) | called by muse, mutect2, varscan2
- OTUD6A | c.696C>G p.P232= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100610922, COSV57972773; called by muse, mutect2, varscan2
- PAK5 | c.819G>T p.L273= | Silent (SNP) | VAF 59/191 reads (31%) | called by muse, mutect2, varscan2
- PCDHA12 | c.2079G>T p.L693= | Silent (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- PCLO | c.15081A>T p.I5027= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV61655800; called by muse, mutect2
- PDE3A | c.3345G>A p.Q1115= | Silent (SNP) | VAF 49/277 reads (18%) | catalogued as rs372016027; called by muse, mutect2, varscan2
- PIK3C2A | c.1305A>T p.L435= | Silent (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.5676C>A p.V1892= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- PLXNC1 | c.4221T>C p.H1407= | Silent (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- RTL10 | c.340C>T p.L114= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.12390G>A p.Q4130= | Silent (SNP) | VAF 69/97 reads (71%) | catalogued as COSV63707608; called by muse, mutect2, varscan2
- SHOX2 | c.414C>T p.I138= (on ENST00000441443 / NM_006884.3; = p.I162= on NM_003030.4) | Silent (SNP) | VAF 72/264 reads (27%) | catalogued as COSV101273783; called by muse, varscan2
- SLCO4A1 | c.286C>T p.L96= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV53892327; called by muse, mutect2, varscan2
- SMARCA2 | c.1353C>T p.Y451= | Silent (SNP) | VAF 132/214 reads (62%) | catalogued as rs948121970; called by muse, mutect2, varscan2
- SORCS1 | c.1365C>G p.V455= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- SPACA9 | c.426C>A p.P142= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- SYCP2 | c.3696T>A p.I1232= | Silent (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- SYNE1 | c.22479G>A p.Q7493= (on ENST00000367255 / NM_182961.4; = p.Q7422= on NM_033071.3) | Silent (SNP) | VAF 69/343 reads (20%) | catalogued as rs1314619363; called by muse, mutect2, varscan2
- SYNE1 | c.13659G>T p.R4553= (on ENST00000367255 / NM_182961.4; = p.R4482= on NM_033071.3) | Silent (SNP) | VAF 59/239 reads (25%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.939C>T p.S313= | Silent (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- TRHR | c.294C>T p.C98= | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as COSV61234281; called by muse, mutect2, varscan2
- TRPM6 | c.3555C>T p.F1185= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- TTC30A | c.1227C>T p.I409= | Silent (SNP) | VAF 84/451 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.89349C>A p.A29783= (on ENST00000591111; = p.A22359= on NM_003319.4) | Silent (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- UBXN2B | c.995A>G p.*332= | Silent (SNP) | VAF 37/56 reads (66%) | called by muse, mutect2, varscan2
- VN1R5 | c.333T>C p.N111= | Silent (SNP) | VAF 75/117 reads (64%) | catalogued as rs1337036576; called by muse, mutect2, varscan2
- VSIR | c.150C>T p.V50= | Silent (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- ZNF23 | c.327A>G p.T109= | Silent (SNP) | VAF 143/371 reads (39%) | called by muse, mutect2, varscan2
- ZNF345 | c.540G>A p.G180= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- ARFRP1 | c.417+524C>G | Intron (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- CCDC141 | c.4325+10C>A | Intron (SNP) | VAF 24/72 reads (33%) | catalogued as rs754956024; called by muse, varscan2
- DCHS2 | n.2143C>G | RNA (SNP) | VAF 90/158 reads (57%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7389C>A | Intron (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- MIR1244-3 | n.84A>G | RNA (SNP) | VAF 31/231 reads (13%) | called by muse, mutect2, varscan2
